Somatic mutation profile of tumor specimen ALCH-AEQJ-TTP1-A (aliquot ALCH-AEQJ-TTP1-A-1-0-D-A627-36) from ALCHEMIST case ALCH-AEQJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.7 years (24,349 days).
Specimen ALCH-AEQJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0dfc5180-cb3b-4c56-bb8a-7ca103ca4e83.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEQJ-NB1-A (Blood Derived Normal), aliquot ALCH-AEQJ-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80bfc593-1cf3-46ea-9842-7dd558ae3cee

The open-access MAF lists 102 somatic variants for this specimen: 71 protein-altering or splice-affecting, 20 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 20, Intron 6, Nonsense Mutation 4, RNA 3, Splice Region 3, 3'UTR 2, In Frame Del 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 91/449 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.673-2A>C p.X225_splice | Splice Site (SNP) | VAF 28/224 reads (13%) | hotspot (GDC flag); catalogued as CS109519, COSV52669186, COSV52682653, COSV52687702; called by mutect2, varscan2
- ADAMTS12 | c.1649C>A p.P550H | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV61266070; called by muse, mutect2, varscan2
- COL10A1 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV54573446; called by muse, mutect2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 6/34 reads (18%) | catalogued as rs754135731; called by mutect2, varscan2
- ETS1 | c.111C>G p.N37K | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV67008981; called by muse, mutect2, varscan2
- FLNC | c.732C>A p.N244K | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV57966700; called by muse, mutect2, varscan2
- GNG2 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 33/294 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs139067662, COSV58915554; called by muse, mutect2, varscan2
- KIAA0100 | c.1420G>T p.V474L | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs1308673878; called by muse, mutect2
- MGA | c.1133A>G p.N378S | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as rs1566988728; called by muse, mutect2, varscan2
- MXRA5 | c.6890G>T p.R2297L | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99476937; called by muse, mutect2
- NCAPD2 | c.1352A>G p.Q451R | Missense Mutation (SNP) | VAF 42/402 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs1182322584; called by muse, mutect2
- NOS2 | c.2509C>A p.P837T | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as rs528170673, COSV100569800; called by muse, mutect2, varscan2
- NRXN1 | c.2953G>A p.D985N | Missense Mutation (SNP) | VAF 28/243 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1553698631, COSV58461614; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR2C3 | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 54/362 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs1233717505, COSV63574756; called by muse, mutect2, varscan2
- PLXNA4 | c.1964A>G p.N655S | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.698); catalogued as rs746877578; called by muse, mutect2, varscan2
- PON1 | c.1042C>T p.H348Y | Missense Mutation (SNP) | VAF 18/509 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV55933704; called by muse, mutect2
- POTEF | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 23/370 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.111); catalogued as rs372132158; called by muse, mutect2
- RAD50 | c.478G>C p.E160Q | Missense Mutation (SNP) | VAF 12/357 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54757854, COSV99529088; called by muse, mutect2
- RFX6 | c.764G>A p.C255Y | Missense Mutation (SNP) | VAF 23/252 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.242); catalogued as rs1451270729; called by muse, mutect2
- SYNE2 | c.10603A>G p.I3535V | Missense Mutation (SNP) | VAF 38/444 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs977173110; called by muse, mutect2
- TUBA4B | c.414C>A p.D138E | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.974); catalogued as COSV67526241; called by muse, mutect2, varscan2
- WDR62 | c.1802C>G p.A601G | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1290682936; called by muse, mutect2
- ZFP91 | c.600G>C p.Q200H | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as rs368219174; called by muse, mutect2, varscan2
- ADAMTS16 | c.2911C>T p.P971S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- AMOT | c.2666C>A p.A889D (on ENST00000371959 / NM_001113490.1; = p.A480D on NM_133265.3) | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.154); called by muse, mutect2
- ANK2 | c.10210C>A p.P3404T | Missense Mutation (SNP) | VAF 26/330 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.306); called by muse, mutect2
- ASB17 | c.49A>T p.N17Y | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- ATF7IP | c.3172G>A p.A1058T | Missense Mutation (SNP) | VAF 54/364 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); called by mutect2, varscan2
- ATF7IP | c.3176del p.N1059Tfs*49 | Frame Shift Del (DEL) | VAF 50/387 reads (13%) | called by mutect2, pindel, varscan2
- CALR | c.152T>G p.L51R | Missense Mutation (SNP) | VAF 24/422 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.332); called by muse, mutect2
- CDH10 | c.1783A>T p.M595L | Missense Mutation (SNP) | VAF 39/299 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDH10 | c.1537G>T p.V513L | Missense Mutation (SNP) | VAF 25/239 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.262); called by muse, mutect2
- COL3A1 | c.3788G>C p.R1263T | Missense Mutation (SNP) | VAF 33/304 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- CTCFL | c.1256A>G p.Q419R | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2
- CTIF | c.260G>T p.S87I | Missense Mutation (SNP) | VAF 33/245 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- DDI2 | c.1066G>T p.G356* | Nonsense Mutation (SNP) | VAF 14/214 reads (7%) | called by muse, mutect2
- DDX41 | c.404G>C p.G135A | Missense Mutation (SNP) | VAF 21/351 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2
- FAM90A26 | c.424T>A p.Y142N | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- FAT2 | c.2296G>T p.E766* | Nonsense Mutation (SNP) | VAF 34/328 reads (10%) | called by muse, mutect2
- FLG | c.7321T>A p.S2441T | Missense Mutation (SNP) | VAF 53/306 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- FNBP1 | c.160C>G p.Q54E | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.791); called by muse, mutect2
- FRY | c.5453A>G p.Q1818R | Missense Mutation (SNP) | VAF 33/350 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.153); called by muse, mutect2
- GOLGB1 | c.7005A>T p.K2335N | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2
- GRIA4 | c.1595C>G p.S532C | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- KANK1 | c.3821C>T p.A1274V | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- KIAA1210 | c.412C>A p.H138N | Missense Mutation (SNP) | VAF 12/336 reads (4%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); called by muse, mutect2
- KLHL31 | c.252T>G p.F84L | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MAGEA11 | c.99G>T p.V33= | Splice Region (SNP) | VAF 9/180 reads (5%) | called by muse, mutect2
- NFASC | c.2284C>A p.R762S (on ENST00000339876 / NM_001378329.1; = p.R758S on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- NLRP14 | c.2987G>C p.C996S | Missense Mutation (SNP) | VAF 21/350 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- NRK | c.3361G>T p.A1121S | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2
- OR6K6 | c.136C>T p.P46S (on ENST00000368144; = p.P22S on NM_001005184.1) | Missense Mutation (SNP) | VAF 23/371 reads (6%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.898); called by muse, mutect2
- OTUD7A | c.1760G>T p.S587I (on ENST00000307050 / NM_001382637.1; = p.S580I on NM_130901.3) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- PFKFB1 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 19/410 reads (5%) | PolyPhen benign (0.133); called by muse, mutect2
- PMF1 | c.360G>T p.E120D | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.178); called by muse, mutect2
- PRAMEF1 | c.413G>T p.C138F | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.861); called by muse, mutect2
- RAB11FIP2 | c.149C>G p.S50C | Missense Mutation (SNP) | VAF 18/504 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2
- RPLP0 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 37/400 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2
- SSR3 | c.7C>G p.P3A | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- TCF12 | c.1888C>A p.L630I | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- TEX13C | c.226G>A p.V76M | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TLL1 | c.1874T>G p.L625R | Missense Mutation (SNP) | VAF 36/415 reads (9%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.999); called by muse, mutect2
- TLR4 | c.260+5T>C | Splice Region (SNP) | VAF 16/289 reads (6%) | called by muse, mutect2
- TMPRSS11E | c.1179C>A p.S393R | Missense Mutation (SNP) | VAF 24/371 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TNFSF18 | c.107C>G p.S36* | Nonsense Mutation (SNP) | VAF 14/476 reads (3%) | called by muse, mutect2
- TRPA1 | c.1644+3A>T | Splice Region (SNP) | VAF 42/474 reads (9%) | called by muse, mutect2
- WDR7 | c.319T>G p.L107V | Missense Mutation (SNP) | VAF 27/247 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- WDR70 | c.1582G>T p.D528Y | Missense Mutation (SNP) | VAF 41/384 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- ZCCHC18 | c.1062G>T p.E354D | Missense Mutation (SNP) | VAF 14/366 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2
- ZCCHC18 | c.1063G>T p.E355* | Nonsense Mutation (SNP) | VAF 14/362 reads (4%) | called by muse, mutect2
- A2M | c.1527G>A p.G509= | Silent (SNP) | VAF 14/209 reads (7%) | called by muse, mutect2
- AHCTF1 | c.3783T>G p.L1261= (on ENST00000366508; = p.L1235= on NM_015446.5) | Silent (SNP) | VAF 18/312 reads (6%) | called by muse, mutect2
- AK9 | c.1821C>A p.I607= | Silent (SNP) | VAF 16/498 reads (3%) | catalogued as rs1328816217; called by muse, mutect2
- ASAP2 | c.2052C>T p.H684= | Silent (SNP) | VAF 20/286 reads (7%) | catalogued as rs370634728; called by muse, mutect2
- CEACAM21 | c.306A>T p.S102= | Silent (SNP) | VAF 26/340 reads (8%) | catalogued as COSV51815666; called by muse, mutect2
- CHSY1 | c.1521C>G p.L507= | Silent (SNP) | VAF 5/89 reads (6%) | called by muse, mutect2
- COL24A1 | c.2499A>T p.P833= | Silent (SNP) | VAF 20/317 reads (6%) | called by muse, mutect2
- DISP3 | c.4035G>T p.A1345= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as COSV99608611; called by muse, mutect2, varscan2
- DOCK2 | c.570A>T p.A190= | Silent (SNP) | VAF 26/258 reads (10%) | called by muse, mutect2
- FAT4 | c.1917G>A p.G639= | Silent (SNP) | VAF 16/276 reads (6%) | called by muse, mutect2
- KCNU1 | c.1635C>G p.L545= | Silent (SNP) | VAF 16/254 reads (6%) | called by muse, mutect2
- MOCS1 | c.576C>T p.R192= | Silent (SNP) | VAF 32/313 reads (10%) | called by muse, mutect2, varscan2
- MXRA5 | c.6888A>C p.G2296= | Silent (SNP) | VAF 14/194 reads (7%) | called by muse, mutect2
- MYBBP1A | c.541C>T p.L181= | Silent (SNP) | VAF 15/117 reads (13%) | called by muse, mutect2, varscan2
- NRCAM | c.2661G>A p.K887= (on ENST00000379028 / NM_001371124.1; = p.K871= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 18/228 reads (8%) | called by muse, mutect2
- SLC30A10 | c.1086C>A p.A362= | Silent (SNP) | VAF 34/634 reads (5%) | called by muse, mutect2
- SLC4A11 | c.2118C>T p.I706= | Silent (SNP) | VAF 9/231 reads (4%) | called by muse, mutect2
- SPATA31D1 | c.15C>G p.L5= | Silent (SNP) | VAF 9/253 reads (4%) | called by muse, mutect2
- TARS1 | c.468T>C p.S156= | Silent (SNP) | VAF 31/231 reads (13%) | catalogued as rs1033943231; called by muse, mutect2, varscan2
- TCTN1 | c.783C>T p.A261= | Silent (SNP) | VAF 48/459 reads (10%) | catalogued as COSV100886216; called by muse, mutect2, varscan2
- ALX1 | c.*33C>G | 3'UTR (SNP) | VAF 29/258 reads (11%) | called by muse, mutect2, varscan2
- AR | c.*21C>A | 3'UTR (SNP) | VAF 14/212 reads (7%) | catalogued as COSV101018539; called by muse, mutect2
- C2CD6 | c.1581+1340A>G | Intron (SNP) | VAF 16/186 reads (9%) | called by muse, mutect2
- DCHS2 | n.5841G>T | RNA (SNP) | VAF 54/608 reads (9%) | called by muse, mutect2
- GALNT9 | c.1077+7200C>G | Intron (SNP) | VAF 12/119 reads (10%) | catalogued as rs913060931; called by muse, mutect2, varscan2
- GULP1 | c.610-1755C>T | Intron (SNP) | VAF 18/200 reads (9%) | called by muse, mutect2
- MIR890 | n.47A>T | RNA (SNP) | VAF 20/165 reads (12%) | called by muse, mutect2, varscan2
- OFCC1 | n.1085C>T | RNA (SNP) | VAF 28/262 reads (11%) | called by muse, mutect2, varscan2
- POLR1C | c.383-16C>T | Intron (SNP) | VAF 30/416 reads (7%) | called by muse, mutect2
- SDCCAG8 | c.675+191C>A | Intron (SNP) | VAF 16/228 reads (7%) | called by muse, mutect2
- SETD5 | c.2725-1911G>A | Intron (SNP) | VAF 14/335 reads (4%) | called by muse, mutect2
